Somatic mutation profile of tumor specimen TARGET-30-PAIXRK-01A (aliquot TARGET-30-PAIXRK-01A-01W) from TARGET case TARGET-30-PAIXRK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.5 years (564 days).
Specimen TARGET-30-PAIXRK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7abfaf01-6817-4dbe-b48c-dfa019bb2c7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIXRK-10A (Blood Derived Normal), aliquot TARGET-30-PAIXRK-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fed93b99-febb-4b43-9a13-b84d08965267

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP3A5 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 344/804 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as COSV56123543; called by muse, mutect2, varscan2
- DSTN | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV55714575; called by muse, mutect2, varscan2
- FAT2 | c.11440G>A p.E3814K | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV55831123; called by muse, mutect2, varscan2
- FUT9 | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV56158451; called by muse, mutect2, varscan2
- GSDMB | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 21/415 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs766087258; called by muse, mutect2
- PCDHA9 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1554143600; called by muse, mutect2
- PCNX3 | c.3136C>G p.R1046G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV63141260; called by mutect2, varscan2
- TLCD3A | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV56747791; called by muse, mutect2, varscan2
- ZFYVE1 | c.2141C>A p.P714H | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59613518; called by muse, mutect2, varscan2
- ZNF324 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV52182729; called by muse, mutect2, varscan2
- ATG9A | c.541_558del p.Q181_R186del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- OR2B2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- CUX2 | c.894G>A p.R298= | Silent (SNP) | VAF 22/181 reads (12%) | catalogued as COSV55649948; called by muse, mutect2, varscan2
- ELP1 | c.3982C>T p.L1328= | Silent (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- ENAM | c.1122A>T p.P374= | Silent (SNP) | VAF 238/533 reads (45%) | catalogued as COSV68537109, COSV68537222; called by muse, mutect2, varscan2
- HIF3A | c.1602C>A p.A534= (on ENST00000377670 / NM_152795.4; = p.A465= on NM_022462.4) | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs749518429, COSV52199399; called by muse, mutect2, varscan2
- STAT6 | c.714A>T p.L238= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV55674603; called by muse, mutect2, varscan2
- TRIM58 | c.834C>T p.C278= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV63572528; called by muse, mutect2
